TCGA case TCGA-UD-AAC6 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Western Australia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98889636-e53c-44df-951e-01a70033e754

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 67 years; Vital status: Dead; Days to death: 456 days (1.2 years).

Diagnoses (3)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,571 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 456 days (1.2 years).
   Pathology details: Consistent pathology review: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 125 days; Days to treatment end: 127 days; Treatment dose: 21 Gy; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed; Days to treatment start: 138 days; Days to treatment end: 256 days; Treatment outcome: Stable Disease.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Pleura, NOS. Age at diagnosis: 67.6 years (24,697 days); Days to diagnosis: 126 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 67.6 years (24,701 days); Days to diagnosis: 130 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 126 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 126 days.
- Day 130 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 130 days.
- Days to follow up: 456 days (1.2 years); Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 0.905 mg/dL [Blood test normal range lower: 0.679; Blood test normal range upper: 1.244].
- Serum Mesothelin 13.4 nmol/L [Blood test normal range lower: 0.3; Blood test normal range upper: 2.5].

Exposures
- Exposure type: Asbestos; Age at last exposure: 25; Age at onset: 24; Exposure duration years: 1; Exposure source: Occupational.
- Occupation duration years: 30; Occupation type: Handicraft Workers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UD-AAC6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-UD-AAC6-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UD-AAC6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UD-AAC6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Window tinting.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma; Serum mesothelin prior treatment: 13.421.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 456 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 456 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 126 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UD-AAC6-01A-11D-A39Q-01): tumor purity 0.48, ploidy 2.27, whole-genome doublings 0.
